Surgical pathology report (de-identified scan), TCGA case TCGA-ZU-A8S4, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Spectrum Health, specimen TCGA-ZU-A8S4-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

-year-old male with right liver lobe lesion

Research Dx

Right partial hepatectomy:

Cholangiocarcinoma, sarcomatous.

ICD-O-3
Cholangiocarcinoma 8160/3
Site: Bile duct, intrahepatic C22.1
JW 1/17/14

CASE SUMMARY FOR CARCINOMA OF INTRAHEPATIC BILE DUCTS:

Specimen: right liver lobe.

Procedure: right hepatic lobectomy.

Tumor size: 8 x 5.5 x 6 cm.

Tumor focality: single focus.

Histologic type: cholangiocarcinoma, sarcomatous (pleomorphic).

Histologic grade: poorly differentiated.

Tumor growth pattern: mass-forming.

Microscopic tumor extension: tumor confined to hepatic parenchyma .

Margins:

Hepatic parenchymal/bile duct margin: negative.

Distance of invasive carcinoma from closest margin: 3 cm

Lymphovascular invasion: not definitively identified.

Perineural invasion: present.

Pathologic staging (pTNM)

Primary tumor (pT): pT1 - solitary tumor without vascular invasion.

Regional lymph nodes (pN): pNX - cannot be assessed.

Distant metastasis (pM): not applicable.

Additional findings: extensive tumor necrosis.

AJCC Staging (7th edition): pT1 pNx pM not applicable

Research QC

Tumor T1:

85% tumor nuclei (not sarcomatoid/pleomorphic)

10% necrosis

5% normal

Tumor T2:

20% tumor nuclei (approx. 1/2 sarcomatoid)

80% necrosis

0% normal

Tumor T3:

33% tumor nuclei (not sarcomatoid)

67% necrosis

0% normal

Normal:

100% liver

Research Specimen

-

Specimen Process Time

Blood draw time:

Plasma frozen time:

[page 2 of 2]
Serum frozen time:
Buffy coat frozen time:

Cold ischemia start time:
Formalin fixation start time:
Total cold ischemia time: 34 minutes
Formalin fixation stopped time:
Total formalin fixation time: Approximately 6 hours

Specimen Weight

T1-101 mg, T2-81mg, T3-100 mg, T4-125 mg
N1-274 mg

Specimen Size

Plasma x 4
Serum x 3
Buffy coat x 1

Cryovials x 8
Normal x 4
Tumor x 4

FFPE x 8
Normal x 4
Tumor x 4

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 9fcbd49b-af4c-462f-b98b-f79dbf313174 (TCGA-ZU-A8S4.92337E74-DF14-48C7-90AC-907A787E1D0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).